TCGA case TCGA-CN-4731 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50e25a4b-2eb2-4770-9a2d-8922a1e0ab56

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 998 days (2.7 years); Cause of death: Cancer Related.

Diagnoses (5)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,194 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2c; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 998 days (2.7 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 3; Lymph nodes tested: 52; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Recurrent Disease; Days to treatment start: 273 days; Days to treatment end: 301 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 273 days; Days to treatment end: 323 days; Treatment dose: 7,000 cGy; Course number: 2; Number of fractions: 35; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, Cyberknife; Initial disease status: Recurrent Disease; Days to treatment start: 538 days (1.5 years); Days to treatment end: 562 days (1.5 years); Treatment dose: 4,400 cGy; Course number: 3; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Recurrent Disease; Days to treatment start: 546 days (1.5 years); Days to treatment end: 560 days (1.5 years); Number of cycles: 3; Treatment dose: 300 mg/mL; Prescribed dose: 100; Prescribed dose units: mg/mL; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Days to treatment start: 827 days (2.3 years); Days to treatment end: 869 days (2.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 937 days (2.6 years); Days to treatment end: 958 days (2.6 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 29 days; Treatment outcome: Persistent Disease.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 64.2 years (23,437 days); Days to diagnosis: 243 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 64.9 years (23,697 days); Days to diagnosis: 503 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.7 years (24,015 days); Days to diagnosis: 821 days (2.2 years); Prior treatment: Yes.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.9 years (24,070 days); Days to diagnosis: 876 days (2.4 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 243 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 243 days.
- Days to follow up: 383 days (1.0 years); Disease response: Tumor Free.
- Day 503 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 503 days (1.4 years).
- Days to follow up: 693 days (1.9 years); Disease response: Tumor Free.
- Day 821 (post initial treatment): Progression or recurrence: Yes.
- Day 876 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 993 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 998 days (2.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Negative.
- EGFR amplification: Not Amplified.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 60; Tobacco smoking quit year: 2009.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-4731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-CN-4731-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30.
  Slide TCGA-CN-4731-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-CN-4731-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-4731-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Buccal Mucosa; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; EGFR amplification status: Unamplified; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 4; Alcohol history documented: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Erbitux.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: erbitux; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: taxotere; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 2: Radiation type other: Cyberknife.
- Follow-up form 1: New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site: Oral Cavity; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No.
- Follow-up form 5: Lost to follow-up: No; Tumor status: With tumor; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: Yes; Cause of death: Related to Head & Neck Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 998 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 998 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 243 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-4731-01A-01D-1432-01): tumor purity 0.63, ploidy 2.04, whole-genome doublings 0.
